Somatic mutation profile of tumor specimen TCGA-LP-A4AW-01A (aliquot TCGA-LP-A4AW-01A-11D-A243-09) from TCGA case TCGA-LP-A4AW, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 52.2 years (19,079 days).
Specimen TCGA-LP-A4AW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a267ae8-e8fd-4344-800d-83083f439080.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LP-A4AW-10A (Blood Derived Normal), aliquot TCGA-LP-A4AW-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eb9207a-f18e-48e1-a67d-4b4a9f245db7

The open-access MAF lists 104 somatic variants for this specimen: 74 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 28, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 2, In Frame Ins 1, RNA 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1740_1742dup p.Y580_L581insF (on ENST00000521381 / NM_181523.3; = p.Y310_L311insF on NM_181504.4) | In Frame Ins (INS) | VAF 20/64 reads (31%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACRBP | c.418G>C p.A140P | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.214); catalogued as COSV57525160; called by muse, mutect2, varscan2
- ACTR6 | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV51843031; called by muse, mutect2, varscan2
- ADAMTS12 | c.3772G>C p.E1258Q | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV61276063; called by muse, mutect2, varscan2
- AHNAK2 | c.13196C>T p.P4399L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60927966; called by muse, mutect2, varscan2
- ALS2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV51889814, COSV51891880; called by muse, mutect2, varscan2
- ARL16 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1490722734, COSV61267127; called by muse, mutect2, varscan2
- ART4 | c.450T>A p.Y150* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV57453087; called by muse, mutect2, varscan2
- BRCA2 | c.9692C>A p.S3231* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV101200912, COSV66337532; called by muse, mutect2, varscan2
- CEL | c.730G>A p.G244S (on ENST00000673714; = p.G241S on NM_001807.6) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs760144206, COSV60829332; called by muse, mutect2, varscan2
- CPT1A | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763042338, COSV55756857; called by muse, mutect2, varscan2
- CREB1 | c.454G>C p.E152Q (on ENST00000432329 / NM_134442.5; = p.E138Q on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62066518; called by muse, mutect2, varscan2
- DHRSX | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58138209; called by muse, mutect2, varscan2
- DNAH5 | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV54247405; called by muse, mutect2, varscan2
- FAM181A | c.408C>A p.D136E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV50891209; called by muse, mutect2, varscan2
- FAT1 | c.5084C>G p.S1695* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV71673281, COSV71675655; called by muse, mutect2, varscan2
- FBN2 | c.5618G>C p.S1873T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV52540517; called by muse, mutect2, varscan2
- FCRL5 | c.843G>C p.Q281H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV62512044, COSV62516284; called by muse, varscan2
- FLG | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs865914246, COSV64247427; called by muse, mutect2, varscan2
- FRZB | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54555812; called by muse, mutect2, varscan2
- FZD5 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1277272323, COSV54944537; called by muse, mutect2
- GARS1 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs775471710, COSV66828418; called by muse, mutect2, varscan2
- GAS6 | c.280+2T>A p.X94_splice | Splice Site (SNP) | VAF 15/46 reads (33%) | catalogued as COSV59855160; called by muse, mutect2, varscan2
- GDF5 | c.1015A>C p.K339Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV65503233; called by mutect2, varscan2
- GDF5 | c.1014G>T p.E338D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV65503243; called by mutect2, varscan2
- HIF3A | c.1853C>A p.P618Q (on ENST00000377670 / NM_152795.4; = p.P549Q on NM_022462.4) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV52203617; called by muse, mutect2, varscan2
- ITGB4 | c.3241G>A p.V1081I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201802102; called by muse, mutect2, varscan2
- KLK9 | c.604G>C p.G202R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51594269; called by muse, mutect2, varscan2
- LEO1 | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV55176539, COSV55177197; called by muse, mutect2, varscan2
- LTO1 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54163451; called by muse, mutect2, varscan2
- MDC1 | c.4351A>G p.T1451A | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV64526930; called by muse, mutect2, varscan2
- MDC1 | c.3799C>G p.Q1267E | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs1263394984, COSV64523937, COSV64526942; called by mutect2, varscan2
- MISP | c.1787C>A p.T596K | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as COSV53122006, COSV99296941; called by muse, mutect2, varscan2
- MSL3 | c.830A>G p.Y277C (on ENST00000312196 / NM_078629.4; = p.Y111C on NM_006800.4) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100385070; called by muse, mutect2, varscan2
- MUC3A | c.8380G>A p.E2794K | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100115386; called by muse, mutect2, varscan2
- NFX1 | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs569829262, COSV65353065; called by muse, mutect2, varscan2
- NHLH2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV57202834; called by muse, mutect2, varscan2
- NOP58 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV51898316; called by muse, mutect2, varscan2
- NPAP1 | c.1652C>T p.T551M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.542); catalogued as COSV61510537; called by muse, mutect2, varscan2
- OPCML | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV59445552; called by muse, mutect2, varscan2
- OXA1L | c.56G>C p.R19P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV53538150; called by muse, mutect2, varscan2
- OXSR1 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV61258456, COSV61260296; called by muse, mutect2, varscan2
- PAX6 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as COSV53795263; called by muse, mutect2, varscan2
- PDCD4 | c.888T>A p.D296E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54525280; called by muse, mutect2, varscan2
- POTEF | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.141); catalogued as rs780600249, COSV62543666; called by muse, mutect2, varscan2
- PRSS53 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54926325; called by muse, mutect2, varscan2
- PSG6 | c.705C>T p.L235= | Splice Region (SNP) | VAF 51/272 reads (19%) | catalogued as COSV99414563; called by muse, mutect2, varscan2
- RALY | c.67G>C p.V23L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55783563; called by muse, mutect2, varscan2
- RECQL4 | c.2590C>G p.Q864E | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as CM151350, COSV99468235; called by muse, mutect2
- RGL2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.223); catalogued as rs1268138720, COSV65842883; called by muse, mutect2
- SCN3A | c.5914A>T p.S1972C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51821758; called by muse, mutect2, varscan2
- SLC13A4 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.179); catalogued as rs543900359, COSV62462582; called by muse, mutect2, varscan2
- SMC1A | c.2382A>C p.E794D | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.166); catalogued as COSV59131536; called by muse, mutect2, varscan2
- SPAG17 | c.6350C>T p.P2117L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV60466776; called by muse, mutect2, varscan2
- SPATA1 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs188290298, COSV99759963; called by mutect2, varscan2
- TBC1D1 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs754075345, COSV54717030; called by muse, mutect2, varscan2
- TJP3 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs150589606; called by muse, mutect2
- TMPRSS6 | c.915G>C p.K305N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV60983105; called by mutect2, varscan2
- TNIP3 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50252910; called by muse, mutect2, varscan2
- TNMD | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.054); catalogued as COSV65977695, COSV65977949; called by muse, mutect2, varscan2
- TPGS2 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs936968300, COSV57541491; called by muse, mutect2, varscan2
- TPST2 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV100114246; called by muse, mutect2, varscan2
- TRPA1 | c.2950A>C p.T984P | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100085202; called by muse, mutect2, varscan2
- TSHZ3 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as COSV53666691, COSV53680708; called by muse, mutect2, varscan2
- TSPAN5 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV59874459, COSV59878465; called by muse, mutect2, varscan2
- TYK2 | c.3056A>G p.Y1019C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53391314; called by muse, mutect2, varscan2
- UBQLNL | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs372374185; called by muse, mutect2
- VCPIP1 | c.2473G>T p.E825* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV60046306, COSV60049865; called by muse, mutect2, varscan2
- ZFHX3 | c.4252C>T p.L1418F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV51732581; called by muse, mutect2, varscan2
- ZNF185 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100248576, COSV59274314, COSV59277882; called by muse, mutect2, varscan2
- LY75 | c.2384-22_2386del p.X795_splice | Splice Site (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel
- SLC25A5 | c.330del p.W110Cfs*32 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | called by mutect2, pindel, varscan2
- SYNE1 | c.5173_5174del p.V1726Sfs*5 (on ENST00000367255 / NM_182961.4; = p.V1733Sfs*5 on NM_033071.3) | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- TBCC | c.616_652del p.V206Cfs*10 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel
- ANGPT2 | c.1449G>A p.S483= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs556882297, COSV57339837; called by muse, mutect2, varscan2
- CACNA1C | c.1935G>A p.L645= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV59762367; called by muse, mutect2, varscan2
- CHST15 | c.1119G>A p.L373= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100655357; called by muse, mutect2, varscan2
- COMTD1 | c.483G>A p.K161= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV53687468; called by muse, mutect2, varscan2
- DDIAS | c.1716A>C p.L572= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV61273119; called by muse, mutect2, varscan2
- FGFR4 | c.1368C>T p.L456= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs201925633, COSV99450902; called by muse, mutect2, varscan2
- GLUD2 | c.819C>T p.G273= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as rs145381711, COSV60152900; called by muse, mutect2, varscan2
- KCNH2 | c.1635C>T p.Y545= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs200692436, COSV100059893; ClinVar: likely benign / uncertain significance / benign; called by muse, mutect2, varscan2
- MED13L | c.4710T>A p.S1570= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99930169; called by muse, mutect2, varscan2
- MTPAP | c.1359C>T p.F453= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs768612271, COSV53935719; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEB | c.15954T>C p.R5318= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs993086996, COSV51453742; called by muse, mutect2, varscan2
- NPHS1 | c.2907G>T p.L969= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100800369, COSV62289678; called by muse, mutect2, varscan2
- NR2E3 | c.1011G>A p.K337= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV58909740; called by muse, mutect2, varscan2
- OBSCN | c.16566C>T p.L5522= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs568217249, COSV99484301; called by muse, mutect2, varscan2
- PCOLCE2 | c.912G>A p.T304= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs767520178, COSV55997614; called by muse, mutect2, varscan2
- RALGAPA2 | c.4740C>T p.F1580= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs780044972, COSV52491071; called by muse, mutect2, varscan2
- RASSF4 | c.510C>T p.N170= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs1490583096, COSV58487690; called by muse, mutect2
- RBM24 | c.606C>T p.T202= (on ENST00000379052 / NM_001143942.2; = p.T157= on NM_153020.2) | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV59004450; called by muse, mutect2, varscan2
- RFX5 | c.678C>T p.V226= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs559709373, COSV51841253; ClinVar: likely benign; called by muse, mutect2
- RTL3 | c.981G>A p.Q327= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV58185588; called by muse, mutect2, varscan2
- SLC18A3 | c.297G>A p.A99= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV60326972; called by muse, mutect2, varscan2
- SYNE1 | c.18297C>A p.L6099= (on ENST00000367255 / NM_182961.4; = p.L6028= on NM_033071.3) | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV55079828; called by muse, mutect2, varscan2
- TMEM132D | c.3102C>T p.P1034= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV101242536, COSV67162106; called by muse, mutect2, varscan2
- TRIM39 | c.507T>C p.T169= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100935917; called by muse, mutect2, varscan2
- TRPM1 | c.1422C>T p.V474= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs373134893; called by muse, mutect2, varscan2
- USP54 | c.3105C>T p.P1035= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV60446883; called by muse, mutect2, varscan2
- ZFPM2 | c.102C>A p.I34= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV68291109; called by muse, mutect2, varscan2
- ZNF484 | c.1254G>A p.G418= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV60259344; called by muse, mutect2, varscan2
- CCL11 | c.-1C>G | 5'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100005659; called by muse, mutect2, varscan2
- FAM86C1P | n.186G>A | RNA (SNP) | VAF 49/251 reads (20%) | catalogued as rs758817897, COSV60641608; called by muse, mutect2, varscan2
